Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4169, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4169-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with metastatic renal cell carcinoma. Cytoreductive right nephrectomy.

Specimens Submitted:

- 1: SP: Portion of right adrenal
- 2: SP: Right kidney and adrenal gland
- 3: SP: Hilar lymph nodes, right

DIAGNOSIS:

- 1) PORTION OF RIGHT ADRENAL GLAND; EXCISION:
- FRAGMENTS OF BENIGN ADRENAL TISSUE.
- 2) KIDNEY AND ADRENAL GLAND, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID AND ACINAR.
- THE TUMOR'S GREATEST DIAMETER IS 9.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- THE TUMOR EXTENDS INTO THE RENAL PELVIS AND INVOLVES SINUS ADIPOSE TISSUE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED. HOWEVER, TUMOR CELL CLUSTERS IN SMALL VEINS ARE IDENTIFIED.
- THE NON-NEOPLASTIC KIDNEY SHOWS INTERSTITIAL CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS UNREMARKABLE.
- 3) LYMPH NODES, RIGHT HILAR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

Gross Description:

- 1) The specimen is received fresh, labeled "Portion of Right Adrenal". It consists of a small segment of adrenal tissue with a small amount of adipose tissue attached measuring 2.0 x 2.0 x 0.8 cm in total. A staple line is attached to the specimen. The specimen is sectioned and entirely submitted.

Summary of Sections:

A – adrenal gland

[page 2 of 2]
2) The specimen is received fresh, labeled "Right Kidney and Adrenal Gland". It consists of a radical nephrectomy specimen weighing in total 820 grams and it has a large amount of perinephric adipose tissue attached. A portion of adrenal gland is identified measuring 3.0 x 1.0 x 0.8 cm. A segment of proximal ureter is also identified measuring 5.0 cm in length and 0.3 cm in diameter. Grossly, the ureteral resection margin and the renal hilar vessel margin are free of tumor. The specimen is bivalved from lateral to medial aspect to reveal a kidney measuring 12.0 x 10.0 x 8.0 cm in which a large tumor mass measuring 9.0 x 8.0 x 7.0 cm is identified, and is replacing almost the entire kidney with a small portion of uninvolved renal parenchyma in the inferior pole of the kidney. The tumor mass has a variegated cut surface ranging from tan-white, focally hemorrhagic area to gelatinous and multiloculated cystic area. The tumor mass grossly extends to but not through the renal capsule. Grossly, tumor mass extensively replaces the renal parenchyma and renal pelvis with focal evidence of invading into the renal pelvis. No gross evidence of renal vein invasion is identified. A portion of tumor is submitted for TPS. Gross photograph taken. Representative sections are submitted.

Summary of Sections:

A – adrenal gland

UM – urethral margin

VM – hilar vessel margin

TP – tumor invading renal pelvis

T – tumor mass and adjacent renal capsule and renal parenchyma

K – uninvolved renal parenchyma

3) The specimen is received in formalin, labeled "Hilar Lymph Nodes, Right". It consists of multiple fragments of tan-yellow adipose tissue aggregating to 3.5 cm. In the adipose tissue, multiple presumptive lymph nodes are identified. The largest lymph node measures 0.6 cm. Lymph nodes are submitted.

Summary of Sections:

BLN – bisected lymph nodes

Summary of Sections:

Part 1: SP: Portion of right adrenal

Block	Sect. Site	PCs
1	A	5

Part 2: SP: Right kidney and adrenal gland

Block	Sect. Site	PCs
1	A	1
1	K	1
8	T	8
2	TP	2
1	UM	1
1	VM	2

Part 3: SP: Hilar lymph nodes, right

Block	Sect. Site	PCs
2	BLN	4

Source: NCI Genomic Data Commons file f06d25bd-2267-4628-93cc-747f7c2e73fd (TCGA-BP-4169.4E8FF4D0-3D8E-48C6-9A76-4B14D970C9F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).